Somatic mutation profile of tumor specimen TARGET-40-NAAWHH-01A (aliquot TARGET-40-NAAWHH-01A-01D) from TARGET case TARGET-40-NAAWHH, project TARGET-OS (Osteosarcoma). Sex at birth: female; Primary diagnosis: Osteosarcoma, NOS; Age at diagnosis: 29.0 years (10,585 days).
Specimen TARGET-40-NAAWHH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 75e7e9dc-015d-45ee-b70f-799546ff52a1.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-NAAWHH-10A (Blood Derived Normal), aliquot TARGET-40-NAAWHH-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/70e1374a-d58e-4407-bcf0-4a5551a4cbd9

The open-access MAF lists 9 somatic variants for this specimen: 7 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 4, Silent 2, Nonsense Mutation 1, Frame Shift Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DNAH10 | c.629dup p.L210Ffs*24 (on ENST00000409039; = p.L149Ffs*24 on NM_207437.3) | Frame Shift Ins (INS) | VAF 20/56 reads (36%) | catalogued as rs757790699; called by mutect2, varscan2
- GORASP1 | c.1064G>A p.R355Q | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.551); catalogued as rs139163342; called by muse, mutect2, varscan2
- PLCL1 | c.280G>A p.V94M | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV70862954; called by muse, mutect2, varscan2
- APBB1 | c.1945del p.A649Lfs*37 | Frame Shift Del (DEL) | VAF 8/26 reads (31%) | called by mutect2, pindel, varscan2
- DCLK2 | c.1451C>A p.S484* | Nonsense Mutation (SNP) | VAF 58/231 reads (25%) | called by muse, varscan2
- PYGO2 | c.547A>T p.M183L | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT tolerated (0.71); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- TTN | c.14308G>T p.V4770L (on ENST00000591111; = p.V3843L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/164 reads (17%) | PolyPhen benign (0.074); called by mutect2, varscan2
- STAG2 | c.783T>C p.N261= | Silent (SNP) | VAF 29/97 reads (30%) | catalogued as rs767741681, COSV54352608; called by muse, mutect2, varscan2
- TTN | c.47190A>T p.G15730= (on ENST00000591111; = p.G8306= on NM_003319.4) | Silent (SNP) | VAF 31/131 reads (24%) | called by muse, mutect2, varscan2
